Surgical pathology report (de-identified scan), TCGA case TCGA-3B-A9HL, project TCGA-SARC (Sarcoma), tissue source site Moffitt Cancer Center, specimen TCGA-3B-A9HL-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

Final Diagnosis

- A. MESENTERIC NODULE, RIGHT COLON, EXCISION:
Well-differentiated liposarcoma, adipocytic type.
No high grade or dedifferentiated area noted.
- B. MESENTERIC NODULE NO. 2, RIGHT COLON, EXCISION:
Well-differentiated liposarcoma.
No high grade or dedifferentiated area noted.
- C. "RIGHT RETROPERITONEAL LIPOSARCOMA WITH RIGHT KIDNEY AND A PORTION OF PSOAS MUSCLE," RADICAL RESECTION:
Dedifferentiated liposarcoma (adipocytic and spindle cell sarcoma)
Tumor size: 18 x 14 x 10.5 cm
Tumor necrosis: Less than 10%
Resection margin: Focally positive for tumor
Other findings: Kidney with benign renal cyst, nephrosclerosis and focal interstitial fibrosis
Benign skeletal muscle adjacent to tumor
Ureteral margin free of tumor (tumor present surrounding ureter)
Vascular margins, free of tumor
- D. RETROPERITONEUM, RIGHT LATERAL MARGIN, EXCISION:
Well-differentiated liposarcoma, 12 x 9 x 2 cm.
Tumor at 0.5 cm from margin (gross measurement).
- E. RETROPERITONEAL TISSUE, POSTERIOR, EXCISION:
Lymph node (1), negative for malignancy.
Benign appearing fatty tissue.
- F. PERIAORTIC NODES, LEFT, EXCISION:
Two nodules present.
Smaller nodule: Well-differentiated liposarcoma, sclerosing, no lymph node identified.
Larger nodule: Dedifferentiated liposarcoma, no lymph node identified.

COMMENT: A Ki-67 stain performed on the larger nodule (block F10) reveals staining in approximately 25% of nuclei (manual estimate).

I, _____ the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically Signed
Out by _____

ICD-O-3
Liposarcoma, dedifferentiated
8858/3
Site: Retroperitoneum
C48.1
9/24/22/14

[page 2 of 3]
- A RIGHT COLONIC MESENTERIC NODULE
- B RIGHT COLONIC MESENTERIC NODULE #2
- C RADICAL RESECTION OF RIGHT RETROPERITONEAL LIPOSARCOMA WITH
RIGHT KIDNEY AND PORTION OF PSOAS MUSCLE
- D RIGHT RETROPERITONEAL LATERAL MARGIN
- E POSTERIOR RETROPERITONEAL TISSUE
- F LEFT PERIAORTIC MASS

Clinical History

RETROPERITONEAL SARCOMA

Preoperative Diagnosis

RETROPERITONEAL SARCOMA.

Gross Description

A. The specimen is received fresh labeled "right colonic mesenteric nodule." The specimen consists of an irregular to roughly ovoid, unoriented fragment of pale yellow, soft tissue measuring 2.8 x 2 x 1 cm. Prior to sectioning, the specimen is inked blue. The specimen is serially sectioned to reveal pale yellow to tan, homogeneous cut surface without evidence of necrosis or hemorrhage. The specimen is submitted entirely in 4 cassettes A1-A4.

B. The specimen is received fresh labeled "right colonic mesenteric nodule No. 2." The specimen consists of an unoriented, ovoid, rubbery tumor nodule (2.5 cm in greatest diameter), with a small amount of lobulated adipose tissue attached. The tumor nodule is grossly encapsulated and is inked black. On sectioning the tumor nodule reveal pale yellow to tan, homogeneous cut surface without evidence of necrosis or hemorrhage. The specimen is submitted entirely in 4 cassettes B1-B4.

C. The specimen is received fresh labeled "radical resection of right retroperitoneal liposarcoma with right kidney and a portion of psoas muscle." The specimen consists of a 187.0 gram, 12.0 x 5.5 x 4.0 cm kidney, which is completely surrounded by perinephric adipose tissue ranging from 1.5 to 3.5 cm in thickness. There is an irregular to roughly ovoid, lobulated, rubbery tumor mass, which is adjacent to the inferior medial pole of the perinephric adipose tissue measuring 18.0 x 14.0 x 10.5 cm and weighing 1900.0 grams. The tumor completely surrounds but does not appear to involve a portion of ureter (14.0 cm in length and 0.3 cm in diameter) and extends to within 1.0 cm of the distal ureteral resection margin. The tumor is partially covered by pink tan to dusky red, focally hemorrhagic peritoneum. There is also an irregular fragment of skeletal muscle attached to the tumor, which measures 5.0 x 3.5 x 1.5 cm. The specimen measures in overall dimension 25.0 x 18.0 x 11.0 cm and weighs 2780.0 grams. Prior to sectioning, the specimen is inked as follows: Distal portion of ureter with adjacent tumor is inked blue, serosa covering tumor is inked green, and the remainder of the resection margin of the tumor is inked black. On sectioning, the tumor reveals variegated, partially pale yellow, lobulated, partially pink tan, focally hemorrhagic whorled cut surface. There are multiple irregular areas of necrosis, which range from 0.5 to 3.0 cm in greatest dimension. These areas occupy less than 10% of the tumor. The tumor is 3.5 cm from the renal capsule, which is grossly unremarkable. The renal capsule has been peeled off to reveal a bosselated surface of the kidney with multiple irregular and stellate retracted scars, which range from 0.5 to 1.5 cm in greatest dimension. A single subcapsular cyst is identified measuring up to 2.0 cm in greatest diameter, which is filled with transparent yellowish fluid. The remaining renal parenchyma is grossly unremarkable. The renal pelvis is dilated up to 4.0 cm in greatest dimension and reveals pink tan, focally erythematous and

[page 3 of 3]
hemorrhagic urothelium. Calyces are lined by tan smooth urothelium. The renal artery and vein and their branches are grossly unremarkable and do not appear to be involved by the tumor.

Representative sections of the specimen are submitted to the

Representative sections of the specimen are submitted in 25 cassettes as follows:

- C1: Resection margins of ureter, renal artery and vein
- C2: Portion of ureter located distal to tumor
- C3-C7: Tumor adjacent to portion of ureter
- C8-C16: Peripheral aspects of tumor in relation to resection margin
- C17-C19: Tumor with overlying peritoneum
- C20-C22: Tumor in relation to closest renal capsule
- C23: Renal pelvis
- C24: Subcapsular cystic lesion of kidney
- C25: Renal parenchyma
- C26: Tumor in relation to closest psoas muscle resection margin.

D. The specimen is received fresh labeled "right retroperitoneal lateral margin." The specimen consists of an irregular, unoriented fragment of lobulated adipose tissue which is partially covered by tan, focally erythematous, smooth and glistening serosa. The specimen measures 12 x 9 x 2 cm. Prior to sectioning, the resection margin is inked black. Sectioning the specimen reveals a single, subserosal potential tumor nodule which measures up to 1.0 cm in greatest dimension. The tumor nodule is 0.5 cm from the closest resection margin. The remaining fibroadipose tissue is grossly unremarkable. Representative sections of the specimen are submitted in 6 cassettes, with tumor nodule in its entirety in cassettes D1-D6.

E. The specimen is received fresh labeled "posterior retroperitoneal tissue." The specimen consists of 5 irregular, unoriented fragments of lobulated adipose tissue, which range from 1 to 3.0 cm in greatest dimension. The specimen is serially sectioned to reveal a grossly unremarkable cut surface. Representative sections of the specimen are submitted in 3 cassettes E1-E3.

F. The specimen is received fresh labeled "left periaortic nodes." The specimen consists of 2 unoriented, roughly ovoid, rubbery, grossly encapsulated tumor nodes, which range from 4 to 6 cm in greatest diameter. Prior to sectioning, the specimen is inked as follows; the biggest tumor nodule is inked black and the small one is inked blue. On sectioning both tumor nodules reveal tan, whorled cut surface without evidence of necrosis or hemorrhage. Representative sections of the specimen are submitted in 10 cassettes as follows:

- F1-F4: Smaller tumor nodule.
- F5-F10: Larger tumor nodule.

Source: NCI Genomic Data Commons file 18513e6a-ef6f-441c-964f-e7cf9e192dd7 (TCGA-3B-A9HL.EEB13F15-22D6-48A8-89E9-56BCE4144E30.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).